Surgical pathology report (de-identified scan), TCGA case TCGA-EB-A5SE, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Asterand, specimen TCGA-EB-A5SE-01A (Primary Tumor).

ICD-O-3
melanoma, nodular 8721/3
Site Skin of Trunk C44.5
JSD 2/18/13

Gross Description:

Microscopic Description:

Diagnosis Details:

Comments:

Formatted Path Reports: SKIN TISSUE CHECKLIST

Specimen type: Excision of tumor

Tumor site: Skin, trunk

Tumor size: 2.8 x 2 x 0.4 cm

Tumor features: None specified

Satellite nodules: Present

Histologic type: Nodular melanoma

Histologic grade: Not specified

Lymph nodes: Not specified

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Tumor is multcentric, 4th level of invasion in bigger nodule, 2 level of invasion in smaller nodule

Comments: Breslow thickness 4.0mm

Source: NCI Genomic Data Commons file 26289597-3919-4046-8e4e-b3a15a38b1ef (TCGA-EB-A5SE.8B3EA5BA-D6BD-4952-8586-57D842351441.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).